Somatic mutation profile of tumor specimen BA2201D (aliquot aq-BA2201D) from BEATAML1.0 case 2291, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.2 years (24,909 days).
Specimen BA2201D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 801ad204-60f6-4b3d-9621-bfa70a7fd1ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2084D (Solid Tissue Normal), aliquot aq-BA2084D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5da60060-08e4-44b3-a7d5-f8139918d95b

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_861insTTGT p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 15/38 reads (39%) | catalogued as COSV51548899, COSV51555098, COSV51559390, COSV51564309; called by mutect2, pindel*
- RTF1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1301560331; called by muse, mutect2, varscan2
- ANKS1B | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLIS1 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2
- POLN | c.915G>T p.V305= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- PDE5A | c.-26A>C | 5'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
